Somatic mutation profile of tumor specimen TCGA-DX-A7EM-01A (aliquot TCGA-DX-A7EM-01A-11D-A36J-09) from TCGA case TCGA-DX-A7EM, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 61.7 years (22,531 days).
Specimen TCGA-DX-A7EM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fcd4a482-2d2b-46a2-8ea5-0c58df4f1cc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A7EM-10A (Blood Derived Normal), aliquot TCGA-DX-A7EM-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4eb7d76-8ffb-4518-9792-234aef170870

The open-access MAF lists 53 somatic variants for this specimen: 39 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 36, Silent 14, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL7B | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs756533515, COSV101012561, COSV65927559; called by muse, mutect2, varscan2
- ARHGAP31 | c.2608A>T p.I870F | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1184020209, COSV99957437; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs761402968, COSV100023376; called by muse, mutect2, varscan2
- B3GNTL1 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as rs751762558, COSV57953282; called by mutect2, varscan2
- BRF1 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV100527557; called by muse, mutect2, varscan2
- BTG4 | c.122C>G p.T41R | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as COSV100604585; called by muse, mutect2, varscan2
- CATSPER1 | c.1777T>G p.C593G | Missense Mutation (SNP) | VAF 89/172 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV100376132; called by muse, mutect2, varscan2
- CCDC18 | c.3740C>T p.S1247F (on ENST00000343253 / NM_001306076.1; = p.S1248F on NM_206886.4) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.405); catalogued as COSV100159809; called by muse, mutect2, varscan2
- CCDC40 | c.3338G>A p.R1113H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs368814379; called by muse, mutect2, varscan2
- CUBN | c.8327C>A p.S2776Y | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100913178; called by muse, mutect2, varscan2
- CYP4A11 | c.788C>G p.T263R | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100152362, COSV100152528; called by muse, mutect2, varscan2
- DDX23 | c.2261G>A p.R754H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56399237; called by muse, varscan2
- DNAH9 | c.11926G>C p.E3976Q | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99307053; called by muse, mutect2, varscan2
- E2F7 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs770647288, COSV59743844; called by muse, mutect2, varscan2
- EFL1 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs763927623, COSV99187915; called by muse, mutect2, varscan2
- GPR34 | c.1033C>T p.R345* | Nonsense Mutation (SNP) | VAF 26/29 reads (90%) | catalogued as rs1269693556, COSV100587546; called by muse, mutect2, varscan2
- GUCD1 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV101238136; called by muse, mutect2
- LPCAT2 | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as COSV100045113; called by muse, mutect2, varscan2
- LPCAT2 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.355); catalogued as COSV100045115; called by muse, mutect2, varscan2
- LPL | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs768128481, COSV100255712, COSV60933287; called by muse, mutect2, varscan2
- MAPKAP1 | c.173A>C p.N58T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.122); catalogued as COSV99785419; called by muse, mutect2, varscan2
- MARCHF7 | c.759C>G p.I253M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as COSV99373950; called by muse, mutect2, varscan2
- MUC16 | c.3979A>G p.T1327A | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); catalogued as rs1165615644, COSV101200606; called by muse, mutect2, varscan2
- OR10Z1 | c.362A>G p.D121G | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100779056; called by muse, mutect2
- OR11L1 | c.167A>G p.H56R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV100869460; called by muse, mutect2, varscan2
- PRTG | c.1829C>T p.T610M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs373946986; called by muse, mutect2, varscan2
- RB1 | c.2211+1G>A p.X737_splice | Splice Site (SNP) | VAF 15/27 reads (56%) | catalogued as CS013111, CS022882, CS040295, COSV57296954, COSV57299779, COSV57305551; called by muse, varscan2
- RTCB | c.1289C>A p.A430E | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53280305, COSV99322333; called by muse, mutect2
- RYR2 | c.4498C>T p.R1500C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs778394498, COSV63680185; called by muse, mutect2, varscan2
- SCN1A | c.4456T>A p.F1486I (on ENST00000303395 / NM_001202435.3; = p.F1475I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100321295; called by muse, mutect2, varscan2
- SEC16A | c.7032G>C p.R2344S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99259551; called by muse, mutect2, varscan2
- SPP2 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV99394665; called by muse, mutect2, varscan2
- SYTL3 | c.1226G>A p.G409E (on ENST00000611299 / NM_001242394.1; = p.G341E on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99792301; called by muse, mutect2, varscan2
- TKTL1 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99474075; called by muse, mutect2, varscan2
- TTC3 | c.367A>G p.K123E | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.07); catalogued as COSV100695820; called by muse, mutect2, varscan2
- ZNF688 | c.232A>G p.M78V | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99794307; called by muse, mutect2, varscan2
- CFAP74 | c.1796T>C p.L599S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- RB1 | c.2173_2174del p.V725Nfs*25 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by pindel, varscan2
- SPATA31A1 | c.2935G>A p.G979S | Missense Mutation (SNP) | VAF 67/252 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- ABCA4 | c.3894C>T p.N1298= | Silent (SNP) | VAF 44/72 reads (61%) | catalogued as COSV100933176; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.495C>G p.L165= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100416717, COSV58445823; called by muse, mutect2, varscan2
- CBR3 | c.792A>T p.P264= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99289867; called by muse, mutect2, varscan2
- CELSR3 | c.45G>T p.S15= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99374366; called by muse, mutect2, varscan2
- HS3ST1 | c.378G>A p.S126= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs190695013, COSV50025408; called by muse, mutect2, varscan2
- KAT7 | c.105A>C p.T35= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV99371977; called by muse, mutect2, varscan2
- MAPT | c.738G>A p.S246= (on ENST00000262410 / NM_001377265.1; = p.S171= on NM_016835.4) | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs776395109, COSV99291003; called by muse, mutect2, varscan2
- OR5AC2 | c.228A>C p.S76= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100684439; called by muse, mutect2, varscan2
- PPP1R13B | c.3072G>A p.A1024= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs375070779; called by muse, mutect2, varscan2
- PPP2R5B | c.423G>A p.L141= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV99376318; called by muse, mutect2, varscan2
- RAG2 | c.189T>A p.S63= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as COSV100271421; called by muse, mutect2, varscan2
- SIDT1 | c.1449C>T p.F483= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs1274560006, COSV99334369; called by muse, mutect2, varscan2
- SMUG1 | c.204C>T p.Y68= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs188545749, COSV54538688; called by muse, mutect2, varscan2
- TTC1 | c.834C>G p.G278= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as COSV99180654; called by muse, mutect2, varscan2
